Gene-level copy-number profile of tumor specimen C3L-06648-02 from CPTAC case C3L-06648, project CPTAC-3 (Stomach — Adenomas and Adenocarcinomas). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Stomach, NOS; AJCC pathologic stage: Stage IIIB; Tumor grade: G3; Age at diagnosis: 53.6 years (19,577 days).
Specimen C3L-06648-02: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Pylorus; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 1f14a1a3-957d-4571-b5fb-3155ed27cec4.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator C3L-06648-31 (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,707 have no estimate.
https://portal.gdc.cancer.gov/files/e7280d51-e4a8-4013-9b9d-8ad5289948d3

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 1: 9,419; copy number 2: 34,229; copy number 3: 12,077; copy number 4: 2,680; copy number 6: 17; copy number 9: 494.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 511 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr8:115,408,496–145,066,685, 494 genes, copy number 9 (broad region; genes not listed).
- chr9:63,581,254–64,413,142, 17 genes, copy number 6: AL591438.1, AL591438.2, CDRT15P7, AL772155.1, AL772155.2, MYO5BP3, CDK2AP2P3, PTGER4P3, CR786580.1, RNA5SP284, DUX4L50, MIR4477B, FRG1JP, AL163540.1, U6, ANKRD20A4P, RNU6-1193P.

Autosomal genes at a single copy (total copy number 1): 6,563. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
